Gene-level copy-number profile of tumor specimen TCGA-AX-A2HK-01A from TCGA case TCGA-AX-A2HK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.5 years (28,316 days).
Specimen TCGA-AX-A2HK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.f7491453-cb3e-4cfc-9636-20b5dd36d1a0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A2HK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ecde03b0-3e97-434a-b5d2-8ae2f7f7aeeb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 700; copy number 2: 2,681; copy number 3: 15,906; copy number 4: 19,410; copy number 5: 11,128; copy number 6: 5,180; copy number 7: 1,544; copy number 8: 1,468; copy number 9: 985; copy number 10: 558; copy number 11: 148; copy number 12: 12; copy number 13: 30; copy number 15: 12; copy number 21: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A2HK-01A-11D-A17C-01): tumor purity 0.89, ploidy 4.2, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,790 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,750,430–9,088,478, 17 genes, copy number 13 (within-gene range 5–13): RPL7P11, RPL7P7, Y_RNA, AL357552.1, AL357552.2, RPL23AP19, ENO1, MIR6728, ENO1-AS1, RNU6-304P, HMGN2P17, AL139415.1, AL139415.2, CA6, RN7SL451P, SLC2A7, SLC2A5.
- chr1:182,982,212–183,598,246, 10 genes, copy number 9–10 (within-gene range 5–10): RNU6-41P, LAMC1, LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1, SMG7.
- chr1:201,622,885–202,319,781, 29 genes, copy number 9 (within-gene range 6–9): NAV1, AC092800.1, IPO9-AS1, MIR5191, AL645504.1, RNU6-501P, MIR1231, IPO9, MIR6739, SHISA4, AL513217.1, LMOD1, TIMM17A, SNORA70H, RPL10P4, RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3, GPR37L1, ARL8A, PTPN7, PTPRVP, LGR6.
- chr1:205,302,063–206,464,443, 38 genes, copy number 11 (within-gene range 6–11): NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B, LEMD1-DT, CDK18, RNU2-19P, MFSD4A, RNU6-418P, ELK4, AC096533.1, SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29, AC119673.1, SLC41A1, AC119673.2, PM20D1, SLC26A9, AL713965.1, RAB7B, CTSE, BX571818.1, RHEX, AC244035.3, AVPR1B, AC244035.1, AC244035.4, RPL22P4, AC244035.2, FAM72A, SRGAP2, AC244023.1.
- chr3:85,799,987–86,496,996, 8 genes, copy number 13: CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070.
- chr3:87,594,838–91,513,775, 27 genes, copy number 10: APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr3:168,666,559–174,286,644, 90 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).
- chr3:173,910,498–185,825,042, 219 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 9–15 (broad region; genes not listed).
- chr8:124,811,042–128,564,679, 62 genes, copy number 10–21 (broad region; genes not listed).
- chr10:5,412,557–5,842,132, 16 genes, copy number 9 (within-gene range 6–9): NET1, CALML5, CALML3-AS1, CALML3, AL732437.1, AL732437.3, AL732437.2, LASTR, AL365356.2, RN7SL445P, ASB13, TASOR2, AL365356.1, GDI2, NRBF2P5, AL596094.1.
- chr12:20,014,780–20,370,262, 4 genes, copy number 13: LINC02398, AC126468.1, LINC02468, AC129102.1.
- chr12:20,449,655–20,450,083, 1 gene, copy number 13: UBE2L2.
- chr14:67,819,779–68,730,218, 7 genes, copy number 9 (within-gene range 4–9): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6.
- chr17:142,789–511,347, 11 genes, copy number 12: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2.
- chr17:523,140–540,576, 1 gene, copy number 12: AC015853.3.
- chr17:21,614,487–22,530,609, 26 genes, copy number 11: AC233702.1, AC233702.4, AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3.
- chr19:27,638,483–40,629,818, 489 genes, copy number 10–11 (within-gene range 4–11) (broad region; genes not listed).
- chr20:49,972,106–50,691,542, 25 genes, copy number 9: RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1.

Autosomal genes at a single copy (total copy number 1): 700. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
